Gene-level copy-number profile of tumor specimen TCGA-WL-A834-01A from TCGA case TCGA-WL-A834, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3.
Specimen TCGA-WL-A834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.f47fde12-11ef-4914-98b6-318abe7f1ebf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WL-A834-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4875616-451f-4be8-9c57-72029a1a9f78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,623; copy number 2: 35,789; copy number 3: 7,665; copy number 4: 4,003; copy number 5: 2,611; copy number 6: 722; copy number 7: 137; copy number 9: 270.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WL-A834-01A-11D-A350-01): tumor purity 0.77, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,736 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:71,943,592–72,279,503, 8 genes, copy number 6 (within-gene range 2–6): LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2.
- chr3:75,678,660–79,767,998, 19 genes, copy number 5–7 (within-gene range 2–7): ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1.
- chr3:79,957,566–198,222,513, 1,874 genes, copy number 5–7 (broad region; genes not listed).
- chr4:1,712,821–1,808,872, 4 genes, copy number 6: AC016773.1, TACC3, TMEM129, FGFR3.
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 5 (within-gene range 3–5): VPS13B.
- chr8:99,340,305–145,066,685, 721 genes, copy number 5 (broad region; genes not listed).
- chr11:32,602,246–32,794,658, 2 genes, copy number 9 (within-gene range 2–9): CCDC73, AL049714.1.
- chr11:35,579,430–35,585,310, 1 gene, copy number 5: AL135934.1.
- chr19:31,520,155–40,299,584, 396 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,610. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
